Somatic mutation profile of tumor specimen MP2PRT-PAUIPC-TMP1-A (aliquot MP2PRT-PAUIPC-TMP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PAUIPC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,222 days).
Specimen MP2PRT-PAUIPC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a353afe-c927-46ac-9a64-20572723c8f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUIPC-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUIPC-NM1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/728c2948-46f2-4db6-8a67-bc7a849f6069

The open-access MAF lists 21 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, 3'UTR 1, Frame Shift Del 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.5434C>T p.R1812C | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs746810662, COSV54028188; called by muse, varscan2
- ARRDC2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 71/1228 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs1324406560; called by muse, mutect2
- CADM1 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 20/359 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59010320; called by muse, mutect2
- ESPNL | c.1777T>C p.C593R | Missense Mutation (SNP) | VAF 32/862 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1387078272; called by muse, mutect2
- GPR45 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 189/775 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV51523244, COSV51525466; called by muse, varscan2
- KCND2 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 33/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs561063026, COSV58568984; called by muse, mutect2
- MYH7B | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV53420654; called by muse, mutect2
- RNF141 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs771510261, COSV56417639; called by muse, varscan2
- ROBO2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 55/673 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1405895921, COSV59908258; called by muse, mutect2
- SEPTIN11 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 44/752 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs773831318, COSV53584149; called by muse, mutect2
- TPH1 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 9/154 reads (6%) | catalogued as rs1466396994, COSV51456629, COSV51458296; called by muse, mutect2
- CD44 | c.232A>G p.R78G | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GLT1D1 | c.821C>A p.P274H (on ENST00000442111 / NM_001366889.1; = p.P194H on NM_144669.3) | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GRM1 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 54/466 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.389); called by muse, varscan2
- MMS22L | c.3254C>A p.P1085H | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TFR2 | c.2357C>A p.A786E | Missense Mutation (SNP) | VAF 56/560 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TPPP | c.386_387del p.K129Rfs*164 | Frame Shift Del (DEL) | VAF 108/568 reads (19%) | called by mutect2, varscan2
- UNC79 | c.7238G>A p.R2413Q (on ENST00000393151 / NM_001346218.2; = p.R2236Q on NM_020818.5) | Missense Mutation (SNP) | VAF 105/589 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- VANGL1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, varscan2
- ZNF423 | c.2844C>T p.F948= (on ENST00000563137 / NM_001379286.1; = p.F940= on NM_015069.4) | Silent (SNP) | VAF 169/583 reads (29%) | catalogued as rs747781524; called by muse, varscan2
- TRABD2A | c.*1C>T | 3'UTR (SNP) | VAF 34/338 reads (10%) | catalogued as rs777472069, COSV99406845; called by muse, varscan2
